Somatic mutation profile of tumor specimen TCGA-HU-A4GH-01A (aliquot TCGA-HU-A4GH-01A-11D-A24D-08) from TCGA case TCGA-HU-A4GH, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 75.2 years (27,473 days).
Specimen TCGA-HU-A4GH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8d52900-a70a-41e3-beb9-236bffe0c34a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-A4GH-10A (Blood Derived Normal), aliquot TCGA-HU-A4GH-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cca958b3-7833-4343-ba4e-20c02e7ba718

The open-access MAF lists 797 somatic variants for this specimen: 643 protein-altering or splice-affecting, 135 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 619, Silent 135, Splice Site 8, Intron 8, Nonsense Mutation 5, Splice Region 4, RNA 4, Frame Shift Del 3, 3'UTR 3, Frame Shift Ins 2, 3'Flank 2, 5'UTR 1.

Variants (750 of 797; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.4727T>G p.L1576R | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as rs1553188682, COSV64672847, COSV64674232; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IL7R | c.1184A>C p.K395T | Missense Mutation (SNP) | VAF 13/65 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.46); PolyPhen benign (0.029); catalogued as COSV57406142, COSV57406506, COSV57407763; called by muse, mutect2, varscan2
- ABCC12 | c.428T>G p.I143S | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV60914548; called by muse, varscan2
- ABCG5 | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs761311404, COSV53210574; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACCS | c.1204C>G p.P402A | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV55458594; called by muse, mutect2
- ADARB1 | c.1541G>A p.R514H (on ENST00000360697 / NM_001346687.2; = p.R474H on NM_001112.4) | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs780427333, COSV62344814; called by muse, mutect2, varscan2
- ADCK2 | c.1117T>G p.F373V | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50781774; called by muse, mutect2, varscan2
- ADCY10 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 29/306 reads (9%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.961); catalogued as rs769019873, COSV63241353; called by muse, mutect2
- ADCY4 | c.800A>T p.K267M | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV53475791; called by muse, mutect2, varscan2
- ADGRB3 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.162); catalogued as COSV65399937; called by muse, mutect2
- ADGRV1 | c.3527T>C p.V1176A | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as COSV67987007; called by muse, mutect2
- ADGRV1 | c.6725T>G p.L2242R | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.429); catalogued as COSV67981643; called by muse, mutect2, varscan2
- AFAP1 | c.1136A>G p.D379G | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV61796023; called by muse, mutect2, varscan2
- AGFG1 | c.1405A>G p.S469G | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.97); catalogued as COSV59512496; called by muse, mutect2, varscan2
- AHCYL1 | c.622T>G p.F208V | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV63208823; called by muse, mutect2, varscan2
- AHNAK | c.1005A>C p.E335D | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.981); catalogued as COSV57216256; called by muse, mutect2
- AKNAD1 | c.1447A>C p.S483R | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.019); catalogued as COSV62199284; called by muse, mutect2, varscan2
- AKR1C2 | c.506A>G p.N169S | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as COSV66333360; called by muse, mutect2, varscan2
- AKR1C4 | c.136T>G p.F46V | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV54123625; called by muse, mutect2
- ANK3 | c.12957A>C p.K4319N (on ENST00000280772 / NM_001320874.2; = p.K943N on NM_001149.3) | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.914); catalogued as COSV55061954; called by muse, mutect2
- ANKS1B | c.1460T>G p.V487G | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV61355270; called by muse, mutect2, varscan2
- AP1M2 | c.1136A>G p.K379R | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as COSV51567568; called by muse, mutect2, varscan2
- APEH | c.1445T>C p.L482P | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV56534136; called by muse, mutect2, varscan2
- APOB | c.1708T>G p.S570A | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as COSV51938708; called by muse, mutect2
- APOB | c.1504T>G p.L502V | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs767615659, COSV51938718; called by muse, mutect2, varscan2
- APOL1 | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as rs1027205673, COSV59869189; called by muse, mutect2
- AQP7 | c.994C>G p.P332A | Missense Mutation (SNP) | VAF 21/423 reads (5%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.028); catalogued as COSV53018831; called by muse, mutect2
- ARFGEF2 | c.2360A>G p.Q787R | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV64212831; called by muse, mutect2, varscan2
- ARFGEF3 | c.1054C>T p.L352F | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52459841; called by muse, mutect2, varscan2
- ARHGAP31 | c.3340C>T p.P1114S | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV51794120; called by muse, mutect2
- ARHGEF17 | c.2625A>C p.E875D | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV55233345; called by muse, mutect2
- ARID1A | c.6074A>C p.K2025T | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV61379348; called by muse, mutect2
- ASPRV1 | c.689A>G p.D230G | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV57228260; called by muse, mutect2
- ATP13A5 | c.324A>C p.E108D | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV60870354; called by muse, mutect2, varscan2
- ATP6V0D2 | c.188A>C p.N63T | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV53415445; called by muse, mutect2, varscan2
- ATP8B2 | c.2999T>C p.L1000P (on ENST00000672630; = p.L967P on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as rs1182915931, COSV59246473; called by muse, mutect2, varscan2
- BACE1 | c.942+2T>A p.X314_splice | Splice Site (SNP) | VAF 4/36 reads (11%) | catalogued as COSV57285104; called by muse, mutect2
- BBX | c.1194A>C p.E398D | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV57886138; called by muse, mutect2, varscan2
- BCKDK | c.424-2A>T p.X142_splice | Splice Site (SNP) | VAF 9/68 reads (13%) | catalogued as COSV54892310; called by muse, mutect2, varscan2
- BCL9 | c.2960T>G p.L987R | Missense Mutation (SNP) | VAF 13/320 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV52345196; called by muse, mutect2
- BEST3 | c.1234A>G p.S412G | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1160699167, COSV58302133; called by muse, mutect2, varscan2
- BFSP1 | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.038); catalogued as COSV64900583; called by muse, mutect2, varscan2
- BICRAL | c.2100A>C p.K700N | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58406209; called by muse, mutect2
- BLK | c.794A>G p.K265R | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as COSV52052866; called by muse, mutect2
- BLM | c.4229T>G p.L1410R | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61924696; called by muse, mutect2
- BMP3 | c.524A>C p.N175T | Missense Mutation (SNP) | VAF 50/175 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.911); catalogued as COSV51086379; called by muse, mutect2, varscan2
- BRF1 | c.643A>C p.K215Q | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as rs1347530018, COSV59269654; called by muse, mutect2
- C1QTNF7 | c.342A>C p.E114D | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV54853294; called by muse, mutect2, varscan2
- C2CD3 | c.2245T>G p.L749V | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as COSV58090121; called by muse, mutect2, varscan2
- C2orf16 | c.1742A>C p.E581A | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.26); catalogued as COSV62676267; called by muse, mutect2, varscan2
- C2orf16 | c.3687A>C p.Q1229H | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as COSV62676274; called by muse, mutect2
- C4orf17 | c.941A>G p.E314G | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV56745220; called by muse, mutect2, varscan2
- C9orf153 | c.86G>A p.C29Y | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.159); catalogued as rs773957102, COSV59251490; called by muse, mutect2, varscan2
- CA10 | c.879C>A p.N293K | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.229); catalogued as COSV99564012; called by muse, mutect2, varscan2
- CA10 | c.878A>C p.N293T | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.288); catalogued as COSV53359160, COSV99564016; called by muse, mutect2, varscan2
- CABP2 | c.605A>G p.D202G | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53708994; called by muse, mutect2
- CAMKMT | c.188G>C p.R63T | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65926315; called by muse, mutect2, varscan2
- CAMTA1 | c.3199A>C p.T1067P | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV57905383; called by muse, mutect2
- CBLN4 | c.188C>A p.S63* | Nonsense Mutation (SNP) | VAF 7/152 reads (5%) | catalogued as COSV50352028, COSV50353254; called by muse, mutect2
- CCDC158 | c.1136T>G p.L379R | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs866873509, COSV66356231; called by muse, mutect2, varscan2
- CCDC40 | c.1640A>G p.K547R | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as COSV66472914, COSV66475586; called by muse, mutect2
- CCDC60 | c.1091A>C p.K364T | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); catalogued as COSV59545058; called by muse, mutect2, varscan2
- CCDC61 | c.181T>C p.F61L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54428936; called by muse, mutect2
- CCDC62 | c.1816T>G p.L606V | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV53434291; called by muse, mutect2, varscan2
- CCDC77 | c.194A>C p.K65T | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV53473365; called by muse, mutect2, varscan2
- CCNDBP1 | c.868G>T p.D290Y | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55747255; called by muse, mutect2, varscan2
- CCR1 | c.149T>C p.V50A | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.103); catalogued as COSV56122380; called by muse, mutect2, varscan2
- CD1A | c.603A>G p.Q201= | Splice Region (SNP) | VAF 10/191 reads (5%) | catalogued as COSV56862209; called by muse, mutect2
- CD300LG | c.204A>C p.E68D | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV53224157; called by muse, mutect2, varscan2
- CDC14B | c.340T>G p.L114V | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV55788825; called by muse, mutect2, varscan2
- CDH11 | c.1460A>G p.K487R | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV51759327, COSV51759358, COSV51764779; called by muse, mutect2, varscan2
- CDH13 | c.1429T>G p.F477V | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51827780; called by muse, mutect2, varscan2
- CDHR3 | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV58418032; called by muse, mutect2
- CDK11B | c.1741T>G p.F581V | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1420640807; called by muse, mutect2
- CDK12 | c.2743C>T p.P915S | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV71001040; called by muse, mutect2, varscan2
- CDK13 | c.4396T>G p.L1466V | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as COSV51701069; called by muse, mutect2
- CELSR2 | c.1882A>G p.S628G | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54773544; called by muse, mutect2
- CENPF | c.6523C>A p.L2175I | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.7); catalogued as COSV65275592; called by muse, mutect2, varscan2
- CEP192 | c.7348C>T p.P2450S | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as COSV58065532; called by muse, mutect2
- CEP68 | c.112A>G p.S38G | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.215); catalogued as COSV53125344; called by muse, mutect2, varscan2
- CEPT1 | c.83C>T p.T28I | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.044); catalogued as COSV64111124; called by muse, mutect2
- CFAP161 | c.439T>G p.F147V | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54429532; called by muse, mutect2, varscan2
- CFAP221 | c.1172T>G p.L391R | Missense Mutation (SNP) | VAF 11/215 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.232); catalogued as COSV54658219; called by muse, mutect2
- CFAP221 | c.1710T>G p.S570R | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.022); catalogued as COSV54658228; called by muse, mutect2, varscan2
- CFAP53 | c.1196T>G p.L399R | Missense Mutation (SNP) | VAF 65/226 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV68352096; called by muse, mutect2, varscan2
- CGNL1 | c.1849A>C p.S617R | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV55569455; called by muse, mutect2, varscan2
- CHAMP1 | c.1991A>T p.D664V | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782385979, COSV63522520; called by muse, mutect2, varscan2
- CHGB | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as rs763399470, COSV66760746; called by muse, mutect2, varscan2
- CISD1 | c.226A>G p.R76G | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs568388348, COSV61703547; called by muse, mutect2, varscan2
- CLCN3 | c.1784T>G p.V595G | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV61627373; called by muse, mutect2, varscan2
- CLDN8 | c.116A>C p.N39T | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54526175; called by muse, mutect2
- CLNK | c.997T>A p.L333M | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57016144; called by muse, mutect2, varscan2
- CNBD1 | c.1187T>G p.L396R | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV73072298, COSV73072404, COSV73073941; called by muse, mutect2, varscan2
- CNBD2 | c.1460A>T p.K487M (on ENST00000373973 / NM_001365709.1; = p.K483M on NM_080834.4) | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.72); catalogued as COSV100839133; called by muse, mutect2
- CNTN3 | c.1615G>T p.G539W | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55173886; called by muse, mutect2
- COL14A1 | c.1869A>C p.E623D | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV52852637; called by muse, varscan2
- COL14A1 | c.2543C>T p.T848M | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs369592872; called by muse, mutect2, varscan2
- COL17A1 | c.2276T>A p.L759H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.148); catalogued as COSV62227274; called by muse, mutect2, varscan2
- COL22A1 | c.1961G>T p.G654V | Missense Mutation (SNP) | VAF 47/335 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs1241962908, COSV57340813; called by muse, mutect2, varscan2
- COL24A1 | c.4697T>A p.L1566H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100992902, COSV65307773; called by muse, mutect2, varscan2
- COL6A6 | c.2035T>G p.F679V | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV62027397; called by muse, mutect2, varscan2
- COL6A6 | c.4739T>C p.L1580P | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); catalogued as COSV62027411; called by muse, mutect2, varscan2
- CPS1 | c.1890A>C p.K630N | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51812670; called by muse, mutect2, varscan2
- CR1L | c.1106A>G p.Q369R | Missense Mutation (SNP) | VAF 16/231 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.474); catalogued as COSV54327131; called by muse, mutect2
- CR2 | c.115A>G p.T39A | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.215); catalogued as COSV65508039; called by muse, mutect2, varscan2
- CRB1 | c.1243T>A p.L415M | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.888); catalogued as rs772721800, COSV66331007; called by muse, mutect2, varscan2
- CSF1R | c.613T>G p.L205V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53836319; called by muse, mutect2, varscan2
- CTC1 | c.3110T>G p.L1037R | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59853625; called by muse, mutect2
- CTNND2 | c.2200A>T p.R734* | Nonsense Mutation (SNP) | VAF 21/123 reads (17%) | catalogued as COSV58894732; called by muse, mutect2, varscan2
- CTSS | c.766C>T p.H256Y | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.649); catalogued as rs1350958032, COSV64566460; called by muse, mutect2, varscan2
- CUL1 | c.1391A>C p.K464T | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.606); catalogued as COSV57389358; called by muse, mutect2, varscan2
- CXCR1 | c.988T>G p.F330V | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV55282159; called by muse, mutect2, varscan2
- CYBB | c.832T>G p.F278V | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66085559; called by muse, mutect2, varscan2
- CYLC1 | c.709A>G p.I237V | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as rs1170464517, COSV61412739; called by muse, mutect2
- CYP24A1 | c.1370T>C p.V457A | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV53774914; called by muse, mutect2
- CYP39A1 | c.1017A>C p.K339N | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs1290215352, COSV51496367; called by muse, mutect2, varscan2
- CYP4V2 | c.374A>T p.K125M | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV66506112; called by muse, mutect2, varscan2
- DBH | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs766166337, COSV55039535; called by muse, mutect2, varscan2
- DCAF10 | c.1673A>C p.K558T | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV54288910; called by muse, mutect2
- DCHS1 | c.7888G>T p.D2630Y | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54998161; called by muse, mutect2, varscan2
- DEFB112 | c.188G>T p.C63F | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100452207, COSV59182687; called by muse, mutect2, varscan2
- DEFB116 | c.235A>G p.K79E | Missense Mutation (SNP) | VAF 14/329 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV68722171; called by muse, mutect2
- DEFB125 | c.140T>G p.L47R | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.153); catalogued as rs1265457055, COSV66703032, COSV66703194; called by muse, mutect2
- DHX30 | c.213A>C p.K71N (on ENST00000445061 / NM_138615.3; = p.K32N on NM_014966.3) | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.174); catalogued as COSV62395165; called by muse, mutect2, varscan2
- DLGAP2 | c.947A>C p.N316T | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV70099462, COSV70102345; called by muse, mutect2
- DMD | c.426C>G p.S142R | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs753380259, COSV55877419; called by muse, mutect2, varscan2
- DNAH1 | c.6802T>G p.F2268V | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV101326459; called by muse, mutect2, varscan2
- DNAH11 | c.2074A>C p.S692R | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV60959834; called by muse, mutect2, varscan2
- DNAH7 | c.4029A>C p.K1343N | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV56768653; called by muse, mutect2
- DNAH9 | c.11770T>G p.F3924V | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.055); catalogued as COSV52353821; called by muse, mutect2, varscan2
- DNAI1 | c.1019+2T>G p.X340_splice | Splice Site (SNP) | VAF 7/33 reads (21%) | catalogued as COSV54279009; called by muse, mutect2, varscan2
- DNMBP | c.1198T>A p.S400T | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV60627179; called by muse, mutect2, varscan2
- DPYD | c.2714C>T p.S905L | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV64600157; called by muse, mutect2
- DQX1 | c.2018C>T p.P673L | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV52046194; called by muse, mutect2, varscan2
- DQX1 | c.985T>G p.F329V | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1343235368, COSV66353277; called by muse, mutect2
- DTNA | c.1604T>C p.L535P | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52007106; called by muse, mutect2, varscan2
- DUSP5 | c.850T>G p.F284V | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63646067; called by muse, mutect2, varscan2
- DUSP9 | c.727T>G p.F243V | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV61437908; called by muse, mutect2, varscan2
- DYNC1H1 | c.6128A>G p.K2043R | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.175); catalogued as COSV64137881, COSV64139901; called by muse, mutect2
- DYNC2H1 | c.6340T>C p.F2114L | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as COSV62086215; called by muse, mutect2
- DYNC2H1 | c.8068T>G p.F2690V | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62096165; called by muse, mutect2
- DZIP1L | c.74A>C p.K25T | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59521492; called by muse, mutect2, varscan2
- EHD4 | c.1322A>G p.E441G | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as COSV55005258; called by muse, mutect2, varscan2
- EIF2D | c.937A>T p.S313C | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55113293; called by muse, mutect2, varscan2
- EIF4G3 | c.4532T>G p.L1511R | Missense Mutation (SNP) | VAF 9/203 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51684319; called by muse, mutect2
- EIF5A | c.377A>C p.K126T | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.732); catalogued as COSV59750342; called by muse, mutect2
- EMC3 | c.572A>C p.N191T | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV55278415; called by muse, mutect2, varscan2
- EMILIN2 | c.2195A>C p.K732T | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as COSV54424440; called by muse, mutect2
- EML1 | c.1083A>C p.E361D | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.052); catalogued as COSV51746458; called by muse, mutect2, varscan2
- ENPP2 | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50010119; called by muse, mutect2, varscan2
- ENPP3 | c.1855A>G p.N619D | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as COSV62954585; called by muse, mutect2, varscan2
- EPHA2 | c.2273T>G p.F758C | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64453375; called by muse, mutect2
- EPX | c.1991A>T p.K664M | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.549); catalogued as COSV56596803; called by muse, mutect2, varscan2
- ERICH5 | c.240A>T p.Q80H | Missense Mutation (SNP) | VAF 5/106 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV59315969; called by muse, mutect2
- ESS2 | c.1325C>T p.P442L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768922267, COSV52817239; called by muse, mutect2, varscan2
- EVI5 | c.1547T>G p.L516R | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1254403787, COSV64825466, COSV64827654; called by muse, mutect2, varscan2
- EXOC2 | c.1590A>C p.E530D | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV57866141; called by muse, mutect2
- EXOC6 | c.1561A>C p.T521P | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53325818; called by muse, mutect2, varscan2
- EXT2 | c.2036A>C p.K679T (on ENST00000343631; = p.K712T on NM_000401.3) | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV59150941; called by muse, mutect2, varscan2
- EXTL1 | c.268A>G p.K90E | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as COSV65337708; called by muse, mutect2, varscan2
- EZR | c.488T>G p.L163R | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61454172; called by muse, mutect2, varscan2
- F8 | c.4254T>G p.I1418M | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.215); catalogued as rs1557278465, COSV64274497; called by muse, mutect2, varscan2
- FAM118B | c.383A>G p.Y128C | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.85); catalogued as COSV64157167; called by muse, mutect2, varscan2
- FAM171B | c.2207T>A p.L736H | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59004154; called by muse, mutect2
- FAM172A | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67938451; called by muse, mutect2
- FAM237A | c.34C>G p.R12G | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.099); catalogued as rs376047346, COSV69305109; called by mutect2, varscan2
- FAM47A | c.2320C>T p.R774C | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1456274810, COSV100650144, COSV60497459; called by muse, mutect2, varscan2
- FAM71A | c.287A>G p.E96G | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV54236010; called by muse, mutect2, varscan2
- FAT2 | c.7766A>C p.E2589A | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as COSV99941668, COSV99943593; called by muse, mutect2
- FAT2 | c.280T>G p.F94V | Missense Mutation (SNP) | VAF 82/278 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55821317; called by muse, mutect2, varscan2
- FAT3 | c.5335A>C p.S1779R | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53121540, COSV99971661; called by muse, mutect2, varscan2
- FBXO15 | c.554T>G p.V185G | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.058); catalogued as rs182315796, COSV54046127; called by muse, mutect2, varscan2
- FBXW10 | c.534T>G p.C178W | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100111582; called by mutect2, varscan2
- FCRL3 | c.759A>C p.E253D | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV63842030; called by muse, mutect2, varscan2
- FGF16 | c.584A>C p.K195T | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV71546214; called by muse, mutect2, varscan2
- FGFR2 | c.2003A>C p.K668T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60649256; called by muse, mutect2, varscan2
- FLG | c.1696A>C p.S566R | Missense Mutation (SNP) | VAF 38/1114 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100911835; called by muse, mutect2
- FLG | c.1216T>A p.S406T | Missense Mutation (SNP) | VAF 39/952 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as rs200489906, COSV64242872; called by muse, mutect2
- FMO4 | c.1586T>G p.L529R | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV63001292; called by muse, mutect2, varscan2
- FMOD | c.790T>G p.F264V | Missense Mutation (SNP) | VAF 27/287 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as COSV61610151; called by muse, mutect2
- FNIP2 | c.2627A>C p.N876T | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.037); catalogued as COSV52440898; called by muse, mutect2
- FRAS1 | c.7631G>C p.S2544T | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.118); catalogued as COSV53617232; called by muse, mutect2
- FRAS1 | c.10283T>C p.L3428P | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53617249; called by muse, mutect2
- G3BP2 | c.1123G>C p.G375R | Missense Mutation (SNP) | VAF 15/231 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62976564; called by muse, mutect2
- GABBR1 | c.1324-2A>T p.X442_splice | Splice Site (SNP) | VAF 9/104 reads (9%) | catalogued as COSV63542920, COSV63544062; called by muse, mutect2
- GABRA5 | c.67A>G p.N23D | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.006); catalogued as COSV100165212, COSV59480755; called by muse, mutect2, varscan2
- GCN1 | c.2606A>C p.N869T | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.335); catalogued as COSV56109142; called by muse, mutect2, varscan2
- GEM | c.497A>G p.E166G | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV52597679; called by muse, mutect2
- GGT6 | c.989C>A p.S330Y (on ENST00000574154 / NM_001122890.3; = p.S298Y on NM_153338.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV54598558, COSV99627310; called by muse, mutect2
- GINM1 | c.661T>G p.L221V | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.487); catalogued as COSV66389909; called by muse, mutect2, varscan2
- GLT1D1 | c.931G>T p.E311* (on ENST00000442111 / NM_001366889.1; = p.E231* on NM_144669.3) | Nonsense Mutation (SNP) | VAF 22/102 reads (22%) | catalogued as COSV55882961; called by muse, mutect2, varscan2
- GPC3 | c.482T>A p.I161N | Missense Mutation (SNP) | VAF 73/164 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.27); catalogued as COSV63665494; called by muse, mutect2, varscan2
- GPR101 | c.323T>G p.V108G | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV53239143; called by muse, mutect2, varscan2
- GPR45 | c.947A>G p.K316R | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV51523831, COSV51524424, COSV51524440; called by muse, mutect2, varscan2
- GPR82 | c.784T>C p.F262L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); catalogued as COSV56887523; called by muse, mutect2, varscan2
- GPSM3 | c.335T>A p.L112H | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66681293; called by muse, mutect2, varscan2
- GRIA3 | c.479A>C p.K160T | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV52058519; called by muse, mutect2
- GRID1 | c.2480A>T p.K827M | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs1216319542, COSV60032968; called by muse, mutect2, varscan2
- GRID1 | c.1640A>C p.K547T | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV60032974; called by muse, mutect2, varscan2
- GRIK3 | c.2038A>T p.T680S | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV66140885; called by muse, mutect2, varscan2
- GRIK4 | c.701T>G p.L234R | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV70801038, COSV70803021; called by muse, mutect2, varscan2
- GRIN3A | c.1634A>C p.D545A | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV62454686; called by muse, mutect2, varscan2
- GRM4 | c.580T>G p.F194V | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV65214394; called by muse, mutect2, varscan2
- GSDMA | c.866T>G p.L289R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56977106; called by muse, mutect2, varscan2
- GSTA1 | c.506A>G p.E169G | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as COSV58015601; called by muse, mutect2
- H2AC21 | c.89G>C p.R30P | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58612220; called by muse, mutect2
- H2BW1 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.36); catalogued as rs782183127, COSV54220471; called by muse, mutect2, varscan2
- HACL1 | c.1636C>G p.L546V | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.616); catalogued as COSV58254837; called by muse, mutect2, varscan2
- HAS2 | c.1648C>T p.L550F | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated, low confidence (0.6); PolyPhen possibly damaging (0.558); catalogued as rs1415034560, COSV58264530; called by muse, mutect2
- HBS1L | c.1975T>G p.F659V | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.524); catalogued as rs562533120, COSV63201502; called by muse, mutect2, varscan2
- HECTD2 | c.1708T>G p.L570V | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53221687; called by muse, mutect2, varscan2
- HECW1 | c.3689A>C p.K1230T | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as COSV67831426; called by muse, mutect2, varscan2
- HELB | c.2653A>C p.T885P | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV56074084; called by muse, mutect2, varscan2
- HEPACAM | c.481A>C p.S161R | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.897); catalogued as COSV53430539; called by muse, mutect2
- HEPACAM | c.224A>C p.K75T | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53430551; called by muse, mutect2, varscan2
- HERC1 | c.7823A>G p.Q2608R | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV71248183; called by muse, mutect2, varscan2
- HFM1 | c.2652T>G p.I884M | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); catalogued as COSV54029027; called by muse, mutect2, varscan2
- HHATL | c.92T>C p.L31P | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as rs1173334757, COSV60042013; called by muse, mutect2, varscan2
- HMCN1 | c.10969A>G p.R3657G | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV54907077; called by muse, mutect2, varscan2
- HOPX | c.52G>A p.E18K (on ENST00000317745; = p.E36K on NM_032495.6) | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV58499939; called by muse, mutect2
- HOXB2 | c.986C>G p.S329C | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.817); catalogued as COSV57487111; called by muse, mutect2, varscan2
- HYDIN | c.2000A>T p.Q667L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV55487759; called by muse, mutect2, varscan2
- IDE | c.1049T>G p.L350R | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1182291447, COSV56423971; called by muse, mutect2, varscan2
- IHH | c.851C>T p.T284M | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.594); catalogued as rs1257383778, COSV55393394; called by muse, mutect2, varscan2
- IL1RAP | c.402A>C p.K134N | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV50763054; called by muse, mutect2, varscan2
- IL1RL1 | c.921T>G p.N307K | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV52116777; called by muse, mutect2
- IMMP2L | c.55T>C p.F19L | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV59244471; called by muse, mutect2, varscan2
- INA | c.1337T>G p.L446R | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV63976093; called by muse, mutect2
- IQCH | c.1187A>C p.K396T | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV60054003; called by muse, mutect2
- IQGAP2 | c.143A>G p.K48R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1239464920, COSV57175068; called by muse, mutect2, varscan2
- ISM1 | c.1036T>G p.F346V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV52605432; called by muse, mutect2, varscan2
- ITGAX | c.1594A>C p.N532H | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51646714; called by muse, mutect2, varscan2
- ITPR3 | c.7934A>G p.E2645G | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65268536; called by muse, mutect2, varscan2
- ITPRIPL1 | c.1007A>G p.K336R (on ENST00000439118 / NM_001008949.3; = p.K344R on NM_178495.6) | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1289294208, COSV63153748; called by muse, mutect2
- ITSN1 | c.1487T>G p.L496R | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66083750; called by muse, mutect2, varscan2
- KALRN | c.3233A>C p.K1078T | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53767087; called by muse, mutect2, varscan2
- KANSL3 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372163152; called by muse, mutect2, varscan2
- KCNB1 | c.1369A>G p.S457G | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.125); catalogued as COSV65568758; called by muse, mutect2
- KCNH4 | c.2636A>C p.K879T | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV52918345; called by muse, mutect2
- KCNJ3 | c.1312C>T p.Q438* | Nonsense Mutation (SNP) | VAF 19/113 reads (17%) | catalogued as COSV54532659, COSV54537413; called by muse, mutect2, varscan2
- KCNK9 | c.431A>C p.K144T | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57282561; called by muse, mutect2, varscan2
- KCNMA1 | c.2015G>A p.R672K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV54234273, COSV54253984; called by muse, mutect2
- KCNMB1 | c.176A>C p.N59T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.346); catalogued as COSV51132649; called by muse, mutect2, varscan2
- KDM3B | c.4428A>C p.E1476D | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV58691333; called by muse, mutect2, varscan2
- KDM5B | c.3376A>G p.S1126G | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.254); catalogued as COSV52508647; called by muse, mutect2, varscan2
- KIAA0100 | c.6086T>A p.F2029Y | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as COSV56382418; called by muse, mutect2
- KIAA0319 | c.118T>G p.L40V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.53); catalogued as COSV65499210; called by muse, mutect2, varscan2
- KIAA1549 | c.655C>G p.P219A | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV54316733; called by muse, mutect2
- KIDINS220 | c.1483T>C p.F495L | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.394); catalogued as rs533098482, COSV56754382; called by muse, mutect2
- KIF2C | c.2098G>C p.V700L | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV64764731; called by muse, mutect2, varscan2
- KIF4B | c.1580T>C p.V527A | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs765952788, COSV70529891; called by muse, mutect2, varscan2
- KIF5C | c.1900T>C p.S634P | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as COSV68481599; called by muse, mutect2
- KIFC3 | c.1253A>T p.N418I | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV65550840; called by muse, mutect2, varscan2
- KIR3DL1 | c.70+2T>C p.X24_splice | Splice Site (SNP) | VAF 28/139 reads (20%) | catalogued as rs1257331530; called by muse, mutect2, varscan2
- KIRREL1 | c.1466A>G p.E489G | Missense Mutation (SNP) | VAF 43/190 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV63287941; called by muse, mutect2, varscan2
- KMT2A | c.1754T>G p.L585R | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV63286776; called by muse, mutect2
- KPRP | c.383T>A p.V128D | Missense Mutation (SNP) | VAF 28/720 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV64221893; called by muse, mutect2
- KRT1 | c.1927A>C p.T643P | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); catalogued as COSV52867252; called by muse, mutect2, varscan2
- KRT1 | c.1070A>G p.Q357R | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV52867263, COSV52870420; called by muse, mutect2
- KRT34 | c.701A>C p.K234T | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.259); catalogued as COSV67449968; called by muse, mutect2, varscan2
- KRT4 | c.782A>C p.K261T | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV53407868; called by muse, mutect2, varscan2
- KRT84 | c.608A>G p.Q203R | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.927); catalogued as COSV57772057; called by muse, varscan2
- LACTB | c.1607A>T p.K536M | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV56056128; called by muse, mutect2
- LAMA2 | c.5932C>A p.L1978I | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as rs368316367, COSV70351327; called by muse, mutect2, varscan2
- LAMA3 | c.1132T>G p.L378V | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as COSV58070372; called by muse, mutect2, varscan2
- LAMA4 | c.3130C>A p.Q1044K (on ENST00000230538 / NM_001105206.3; = p.Q1037K on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.911); catalogued as COSV57898611; called by muse, mutect2
- LCA5 | c.1932A>C p.K644N | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.955); catalogued as COSV63971703; called by muse, mutect2, varscan2
- LILRB1 | c.299A>C p.K100T (on ENST00000427581; = p.K64T on NM_006669.6) | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV61118880; called by muse, mutect2, varscan2
- LILRB2 | c.457T>C p.F153L | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs1423012628, COSV100078994, COSV58745954; called by muse, mutect2
- LILRB5 | c.4A>C p.T2P | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV60258143; called by muse, mutect2, varscan2
- LIMA1 | c.294G>T p.R98S | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV100372591; called by muse, mutect2
- LMNTD1 | c.109T>C p.S37P | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV51447725; called by muse, mutect2, varscan2
- LNPEP | c.2983T>G p.F995V | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV51478465; called by muse, mutect2
- LPAR4 | c.974A>C p.N325T | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV70912753; called by muse, mutect2
- LPL | c.1276T>C p.F426L | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.291); catalogued as rs902905708, COSV60931461; called by muse, mutect2
- LRGUK | c.1745C>T p.A582V | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.446); catalogued as COSV53633871, COSV53638864; called by muse, mutect2, varscan2
- LRRC41 | c.551A>T p.N184I | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV58440377; called by muse, mutect2
- LRRC8E | c.413A>G p.K138R | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV60718375; called by muse, mutect2, varscan2
- LSM14B | c.947A>C p.K316T | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53379158; called by muse, mutect2, varscan2
- LTK | c.2434T>G p.L812V | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.047); catalogued as COSV99541072; called by muse, mutect2, varscan2
- MAN2C1 | c.1060C>G p.Q354E | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1447644305, COSV51230256; called by muse, mutect2
- MAOA | c.927T>G p.Y309* | Nonsense Mutation (SNP) | VAF 3/47 reads (6%) | catalogued as COSV100108878; called by muse, mutect2
- MAP1B | c.5063A>C p.D1688A | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV57100493; called by muse, mutect2, varscan2
- MAP2 | c.1230A>C p.E410D | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.571); catalogued as rs780766647, COSV52280860; called by muse, mutect2, varscan2
- MAP2 | c.2709A>C p.K903N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52294101; called by muse, mutect2, varscan2
- MAP4 | c.1365A>C p.E455D | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.026); catalogued as COSV64241024; called by muse, mutect2, varscan2
- MAPRE2 | c.638A>C p.K213T | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.093); catalogued as COSV55819497; called by muse, mutect2
- MAPRE2 | c.767T>G p.L256R | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.793); catalogued as COSV55819507; called by muse, mutect2, varscan2
- MARCHF6 | c.871T>G p.F291V | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56882344; called by muse, mutect2, varscan2
- MAST1 | c.2788A>C p.S930R | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as COSV52248247; called by muse, mutect2, varscan2
- MAVS | c.122G>C p.R41P | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV63927082; called by muse, mutect2, varscan2
- MBNL3 | c.311T>C p.L104P | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.753); catalogued as COSV63731006; called by muse, mutect2, varscan2
- MBTD1 | c.638A>G p.E213G | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.027); catalogued as COSV64503546; called by muse, mutect2, varscan2
- MCM2 | c.1520C>G p.P507R | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.961); catalogued as COSV54034331; called by muse, mutect2, varscan2
- MCMDC2 | c.1436T>G p.I479S | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV58036607; called by muse, mutect2, varscan2
- ME2 | c.536T>G p.I179S | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58423549; called by muse, mutect2, varscan2
- MGAT4A | c.1475T>G p.F492C | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53847707; called by muse, mutect2
- MGAT5 | c.849T>G p.F283L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (1); PolyPhen probably damaging (0.969); catalogued as COSV56097324; called by muse, mutect2
- MIA3 | c.717A>C p.K239N | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV60513894; called by muse, mutect2
- MNDA | c.865T>G p.F289V | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.014); catalogued as COSV63741037; called by muse, mutect2
- MRGPRX2 | c.511T>A p.L171I | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); catalogued as COSV61674306; called by muse, mutect2, varscan2
- MRTO4 | c.575T>G p.L192R | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs553525688, COSV57674049; called by muse, mutect2, varscan2
- MS4A10 | c.362A>C p.K121T | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV57632860; called by muse, mutect2, varscan2
- MS4A6A | c.74A>G p.E25G | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as COSV60619326; called by muse, mutect2, varscan2
- MTDH | c.1649C>G p.T550S | Missense Mutation (SNP) | VAF 5/125 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100292266, COSV60346376; called by muse, mutect2
- MTMR11 | c.806T>G p.L269R (on ENST00000439741 / NM_001145862.2; = p.L197R on NM_181873.3) | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63806700; called by muse, mutect2, varscan2
- MUC16 | c.40616A>C p.K13539T | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.97); catalogued as COSV66693028; called by muse, mutect2, varscan2
- MUC16 | c.7126A>G p.T2376A | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV67472076; called by muse, mutect2, varscan2
- MUC16 | c.5939T>G p.I1980S | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.702); catalogued as COSV67441873, COSV67472084; called by muse, mutect2, varscan2
- MUC17 | c.6316A>C p.S2106R | Missense Mutation (SNP) | VAF 27/264 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV60291262; called by muse, mutect2, varscan2
- MYH1 | c.4705T>G p.L1569V | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV56850000; called by muse, mutect2, varscan2
- MYH10 | c.248A>C p.K83T | Missense Mutation (SNP) | VAF 61/160 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52601059; called by muse, mutect2, varscan2
- MYH3 | c.2219A>C p.K740T | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56865995; called by muse, mutect2, varscan2
- MYH7 | c.4492T>G p.F1498V | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV62520107; called by muse, mutect2
- MYH8 | c.1738T>G p.F580V | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV67966448; called by muse, mutect2, varscan2
- MYO5A | c.2429A>C p.K810T | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV62559236, COSV62560912; called by muse, mutect2
- MYO7B | c.416A>C p.N139T | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV67348462; called by muse, mutect2, varscan2
- MYO7B | c.1625A>C p.K542T | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV67348463; called by muse, mutect2, varscan2
- MYT1 | c.2321A>C p.K774T | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV60507074; called by muse, mutect2
- NAALAD2 | c.296A>C p.K99T | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.025); catalogued as COSV58961637, COSV58961852; called by muse, mutect2, varscan2
- NCOA3 | c.1480T>C p.S494P | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV59069519; called by muse, mutect2
- NCOA6 | c.6056G>C p.R2019P | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV62864487, COSV62865553; called by muse, mutect2
- NCOR2 | c.1679A>G p.E560G | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.737); catalogued as COSV62299200; called by muse, mutect2
- NDST4 | c.2203A>C p.K735Q | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV99997151; called by muse, mutect2
- NEBL | c.1280T>G p.L427R | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.102); catalogued as COSV65803523; called by muse, mutect2
- NEIL3 | c.1103A>G p.N368S | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.715); catalogued as COSV52811079; called by muse, mutect2, varscan2
- NELL1 | c.2116G>A p.G706R | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54273957; called by muse, mutect2
- NLRP8 | c.1675T>G p.L559V | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV52588779; called by muse, mutect2
- NOLC1 | c.166T>G p.F56V | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV64180588; called by muse, mutect2, varscan2
- NOP14 | c.83A>C p.N28T | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.062); catalogued as COSV58625748; called by muse, mutect2, varscan2
- NOS1 | c.1861T>G p.L621V | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV57614188; called by muse, mutect2
- NOS1 | c.1232A>C p.K411T | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57614197; called by muse, mutect2, varscan2
- NPAP1 | c.2380A>C p.S794R | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.19); catalogued as COSV61507799; called by muse, mutect2
- NPAS4 | c.594A>T p.R198S | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.221); catalogued as COSV60650888; called by muse, mutect2, varscan2
- NPAS4 | c.1684T>G p.F562V | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as COSV60650895; called by muse, mutect2
- NR1I3 | c.330A>C p.Q110H | Missense Mutation (SNP) | VAF 16/416 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV63468236; called by muse, mutect2
- NRBP1 | c.1271T>C p.V424A | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV51994468; called by muse, mutect2
- NRDC | c.1983A>C p.E661D | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as COSV61405017; called by muse, mutect2, varscan2
- NRDE2 | c.1555T>C p.F519L | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as COSV62963525; called by muse, mutect2
- NSUN7 | c.346A>C p.S116R | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.668); catalogued as COSV57274319; called by muse, mutect2, varscan2
- NT5C3B | c.359A>G p.K120R | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.196); catalogued as COSV54056285; called by muse, mutect2, varscan2
- NTNG1 | c.1010C>G p.P337R | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.796); catalogued as COSV99638492; called by muse, mutect2
- NTNG1 | c.1190A>C p.E397A | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.136); catalogued as COSV64272827; called by muse, mutect2, varscan2
- NUMA1 | c.6133C>T p.R2045C | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs113245212, COSV52621283; called by muse, mutect2, varscan2
- NUP188 | c.3210A>C p.K1070N | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.122); catalogued as COSV65362842; called by muse, mutect2
- NUP210L | c.3020T>G p.L1007R | Missense Mutation (SNP) | VAF 25/266 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55149449; called by muse, mutect2
- NYNRIN | c.4639T>C p.S1547P | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.157); catalogued as COSV66843030; called by muse, mutect2, varscan2
- OBSCN | c.15064A>G p.S5022G | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV52782928; called by muse, mutect2
- OPTC | c.463A>T p.T155S | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV65867939; called by muse, mutect2
- OR10J1 | c.112A>C p.T38P | Missense Mutation (SNP) | VAF 168/332 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV71128877, COSV71128961; called by muse, varscan2
- OR10J3 | c.434T>G p.L145R | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100171945, COSV59954527; called by muse, mutect2, varscan2
- OR10J5 | c.43T>G p.L15V | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.248); catalogued as rs775311155, COSV58385605, COSV58386192, COSV58386357; called by muse, mutect2
- OR10X1 | c.686T>A p.L229H | Missense Mutation (SNP) | VAF 8/226 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100936686; called by muse, mutect2
- OR11G2 | c.514A>C p.T172P | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV62132429, COSV62132811; called by muse, mutect2, varscan2
- OR14J1 | c.5T>G p.V2G | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV65845732; called by muse, mutect2, varscan2
- OR1E2 | c.625T>G p.F209V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV50265739; called by muse, mutect2, varscan2
- OR1L4 | c.610A>T p.T204S | Missense Mutation (SNP) | VAF 66/286 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.061); catalogued as COSV52340666; called by muse, mutect2, varscan2
- OR2AK2 | c.540A>C p.E180D | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.198); catalogued as COSV63547689, COSV63557042; called by muse, mutect2, varscan2
- OR2H2 | c.199T>G p.L67V | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.099); catalogued as COSV63542917; called by muse, mutect2, varscan2
- OR2M3 | c.939A>C p.*313Cext*3 | Nonstop Mutation (SNP) | VAF 19/123 reads (15%) | catalogued as COSV101513482; called by muse, mutect2, varscan2
- OR4A15 | c.71T>G p.V24G | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.266); catalogued as COSV59035648; called by muse, mutect2, varscan2
- OR4A47 | c.314T>C p.F105S | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.035); catalogued as COSV71445015; called by muse, mutect2, varscan2
- OR4K1 | c.461T>G p.L154R | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV53460540; called by muse, mutect2, varscan2
- OR4X2 | c.708C>A p.F236L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV56582146; called by muse, mutect2, varscan2
- OR52E8 | c.719T>G p.L240R | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV66207452; called by muse, mutect2
- OR56B4 | c.683T>G p.L228R | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57204722; called by muse, mutect2, varscan2
- OR5A2 | c.298A>G p.T100A | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV100119779, COSV57391186; called by muse, mutect2, varscan2
- OR5H15 | c.35T>G p.F12C | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV62948283; called by muse, mutect2
- OR6X1 | c.626T>G p.L209R | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60009909; called by muse, mutect2, varscan2
- OR6Y1 | c.875C>A p.P292H | Missense Mutation (SNP) | VAF 26/300 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56929709; called by muse, mutect2
- OR7E24 | c.374T>G p.F125C | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV71702241; called by muse, mutect2, varscan2
- OR8B12 | c.104C>T p.T35M | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs146463957; called by muse, mutect2, varscan2
- OR9A2 | c.490T>G p.F164V | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV63306697; called by muse, mutect2
- OSBP | c.2347T>G p.L783V | Missense Mutation (SNP) | VAF 47/186 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV55663403; called by muse, mutect2, varscan2
- OSBPL6 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 69/284 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.165); catalogued as COSV51920128, COSV99506400; called by muse, mutect2, varscan2
- OSCAR | c.107A>G p.K36R | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.105); catalogued as COSV52927757; called by muse, mutect2, varscan2
- OTOA | c.2213A>G p.K738R (on ENST00000286149; = p.K724R on NM_144672.4) | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.52); catalogued as COSV53756150; called by muse, mutect2
- P4HB | c.977A>G p.K326R | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV58941811; called by muse, mutect2, varscan2
- PALD1 | c.2144T>C p.L715P | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs757741108, COSV54974593; called by muse, mutect2, varscan2
- PALMD | c.725T>G p.L242R | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV54164967; called by muse, mutect2
- PBXIP1 | c.2065T>G p.F689V | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV63777304; called by muse, mutect2
- PCDH17 | c.248T>C p.L83P | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV64974981; called by muse, mutect2, varscan2
- PCDHA10 | c.1202A>C p.K401T | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.411); catalogued as COSV56510183; called by muse, mutect2, varscan2
- PCDHA11 | c.120A>C p.K40N | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); catalogued as COSV56510242; called by muse, mutect2, varscan2
- PCDHB16 | c.1219A>G p.R407G | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV53363723; called by muse, mutect2, varscan2
- PCDHGB4 | c.927A>C p.E309D | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as rs375009380; called by muse, mutect2, varscan2
- PCLO | c.2023T>G p.S675A | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV61640086; called by muse, mutect2, varscan2
- PDE1C | c.533A>T p.E178V | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.261); catalogued as COSV58516410; called by muse, mutect2, varscan2
- PDE9A | c.1553A>C p.K518T | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV52327133; called by muse, mutect2, varscan2
- PDHX | c.680A>G p.K227R | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs1554988660, COSV57166709; called by muse, mutect2
- PEG3 | c.1198G>A p.G400R | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV55636254, COSV55645304; called by muse, varscan2
- PEX11B | c.302A>T p.N101I | Missense Mutation (SNP) | VAF 12/247 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV57162759; called by muse, mutect2
- PEX7 | c.604T>G p.L202V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV59249849; called by muse, mutect2, varscan2
- PGBD4 | c.995A>C p.N332T | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV56628060; called by muse, mutect2, varscan2
- PGGHG | c.1789T>G p.F597V | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV66888217; called by muse, mutect2, varscan2
- PGK2 | c.552A>C p.K184N | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as COSV59163221, COSV59164170; called by muse, mutect2
- PHETA2 | c.19A>G p.S7G | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV58790979; called by muse, varscan2
- PHF21A | c.776T>G p.L259R (on ENST00000418153 / NM_001101802.3; = p.L260R on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV99138896; called by muse, mutect2, varscan2
- PHTF2 | c.1760T>G p.L587R (on ENST00000248550 / NM_001366089.1; = p.L549R on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV50328211; called by muse, mutect2, varscan2
- PKD1 | c.6022T>G p.F2008V | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51917997; called by muse, mutect2, varscan2
- PLA2G15 | c.319T>G p.F107V | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.136); catalogued as COSV54723406; called by muse, mutect2, varscan2
- PLA2G4D | c.1069T>C p.F357L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV51821311; called by muse, mutect2
- PLAC1 | c.275T>G p.V92G | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV63656115; called by muse, mutect2, varscan2
- PLCH2 | c.1982A>G p.Q661R | Missense Mutation (SNP) | VAF 56/90 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.348); catalogued as COSV53944258; called by muse, mutect2, varscan2
- PLD1 | c.1502A>C p.K501T | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV60569116; called by muse, mutect2
- PMS2 | c.1940A>C p.K647T | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV56222015; called by muse, mutect2, varscan2
- PNMA8B | c.68T>C p.V23A | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV66536789; called by muse, mutect2
- PNPLA7 | c.115T>G p.F39V | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.058); catalogued as COSV53000166; called by muse, mutect2
- POLR1C | c.671A>C p.K224T | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54831001; called by muse, mutect2
- POMZP3 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.836); catalogued as COSV99300619; called by muse, mutect2
- POPDC3 | c.294A>C p.Q98H | Missense Mutation (SNP) | VAF 59/270 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV54644484; called by muse, mutect2, varscan2
- PPFIA1 | c.3026T>G p.V1009G | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV54136080; called by muse, mutect2, varscan2
- PPM1E | c.533T>C p.L178P | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57575399; called by muse, mutect2, varscan2
- PPP1R3A | c.51A>C p.E17D | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); catalogued as rs762154976, COSV52884373; called by muse, mutect2, varscan2
- PPP1R8 | c.904G>A p.D302N (on ENST00000311772 / NM_014110.5; = p.D78N on NM_002713.4) | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as COSV52580167; called by muse, mutect2, varscan2
- PPP2R2A | c.927A>T p.K309N | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as COSV60097382; called by muse, mutect2
- PPP4R4 | c.1050A>C p.Q350H | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV58555267; called by muse, mutect2, varscan2
- PRAG1 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.543); catalogued as COSV58162139; called by muse, mutect2, varscan2
- PRAMEF15 | c.614A>C p.N205T | Missense Mutation (SNP) | VAF 28/384 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as rs1345568719; called by muse, mutect2, varscan2
- PRC1 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs778285093, COSV62695607; called by muse, mutect2, varscan2
- PRDM15 | c.1123A>G p.T375A | Missense Mutation (SNP) | VAF 9/201 reads (4%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1297793131, COSV54154121; called by muse, mutect2
- PRDM2 | c.1750G>C p.D584H | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52448644, COSV99340740; called by muse, mutect2, varscan2
- PREX2 | c.4334A>C p.N1445T | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV55775997; called by muse, mutect2, varscan2
- PRICKLE1 | c.1121A>G p.K374R | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV61543797; called by muse, mutect2, varscan2
- PRKAG3 | c.845A>G p.K282R | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.14); catalogued as COSV52102201; called by muse, mutect2, varscan2
- PRKCQ | c.836A>C p.N279T | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54112612; called by muse, mutect2, varscan2
- PRKCQ | c.312A>T p.E104D | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.978); catalogued as COSV54112633; called by muse, mutect2, varscan2
- PRR3 | c.452T>C p.V151A | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.068); catalogued as COSV64835285; called by muse, mutect2
- PSEN2 | c.704T>G p.I235S | Missense Mutation (SNP) | VAF 4/81 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100423190; called by muse, mutect2
- PSG1 | c.607T>G p.F203V | Missense Mutation (SNP) | VAF 76/396 reads (19%) | SIFT tolerated (0.95); PolyPhen benign (0.026); catalogued as COSV54950955; called by muse, mutect2, varscan2
- PSME4 | c.4595A>G p.E1532G | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.118); catalogued as COSV66365571; called by muse, mutect2
- PTPDC1 | c.1685A>C p.E562A (on ENST00000375360 / NM_177995.3; = p.E614A on NM_152422.4) | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV56623749; called by muse, mutect2
- PTPRD | c.3685G>A p.V1229M | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV61954221; called by muse, mutect2, varscan2
- PTPRD | c.1817A>G p.Q606R | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV61954261; called by muse, mutect2
- PTPRT | c.2221G>A p.V741M | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.615); catalogued as COSV61987429; called by muse, mutect2, varscan2
- RAD17 | c.1558A>C p.S520R (on ENST00000380774 / NM_133339.2; = p.S509R on NM_002873.1) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV51458129; called by muse, mutect2, varscan2
- RANGAP1 | c.533A>G p.K178R | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.04); catalogued as COSV62363711; called by muse, mutect2, varscan2
- RAPSN | c.608A>C p.K203T | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV54084654; called by muse, mutect2
- RASGRP2 | c.1312T>G p.F438V | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as COSV62449741; called by muse, mutect2, varscan2
- RASL11B | c.383T>A p.L128H | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); catalogued as COSV50535294; called by muse, mutect2, varscan2
- RBM46 | c.391T>G p.F131V | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as COSV55979450; called by muse, mutect2, varscan2
- RDH16 | c.722A>C p.K241T | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV62458259; called by muse, mutect2, varscan2
- RFTN2 | c.586A>C p.S196R | Missense Mutation (SNP) | VAF 51/191 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV54389151, COSV99695348; called by muse, mutect2, varscan2
- RFX6 | c.719T>G p.L240R | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as COSV60585967; called by muse, mutect2, varscan2
- RFX6 | c.1168T>G p.L390V | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.281); catalogued as COSV60585974; called by muse, mutect2, varscan2
- RGS12 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as rs1399694003, COSV60906171; called by muse, mutect2
- RGS18 | c.205T>G p.L69V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.071); catalogued as COSV66508456; called by muse, mutect2
- RGS22 | c.1698A>C p.E566D | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.104); catalogued as COSV62662873; called by muse, mutect2, varscan2
- RIBC1 | c.317A>C p.K106T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.316); catalogued as COSV51448214; called by muse, mutect2
- RMC1 | c.794A>T p.K265M | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV52572373; called by muse, mutect2, varscan2
- RNF17 | c.344A>C p.K115T | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.154); catalogued as COSV55035755, COSV55041940; called by muse, mutect2, varscan2
- ROBO1 | c.179G>T p.R60L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV71395393; called by muse, mutect2, varscan2
- RP2 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 62/69 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54462338; called by muse, mutect2, varscan2
- RPTN | c.623A>C p.K208T | Missense Mutation (SNP) | VAF 42/548 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV60167538; called by muse, mutect2
- RRP12 | c.674A>T p.D225V | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV59668372; called by muse, mutect2, varscan2
- RSPH14 | c.794A>C p.K265T | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53267230; called by muse, mutect2, varscan2
- RXFP2 | c.774A>C p.Q258H | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1473566853, COSV53636515; called by muse, mutect2, varscan2
- RYR2 | c.4475A>G p.E1492G | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV63685265; called by muse, mutect2, varscan2
- SALL1 | c.188A>C p.K63T | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV51758810; called by muse, mutect2, varscan2
- SALL3 | c.1963T>C p.S655P | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.963); catalogued as COSV73306122; called by muse, mutect2, varscan2
- SAP30BP | c.601+1G>A p.X201_splice | Splice Site (SNP) | VAF 47/175 reads (27%) | catalogued as COSV53128368; called by muse, mutect2, varscan2
- SCGB1D1 | c.137T>C p.L46P | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60377646; called by muse, mutect2, varscan2
- SCN9A | c.551T>G p.L184R | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57612556; called by muse, mutect2, varscan2
- SCRT1 | c.35T>G p.L12R | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV59781383; called by muse, mutect2
- SCTR | c.1140+1del p.X380_splice | Splice Site (DEL) | VAF 33/80 reads (41%) | catalogued as rs1338418305; called by mutect2, pindel, varscan2
- SELENBP1 | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 36/362 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.155); catalogued as rs750981873, COSV64373624; called by muse, mutect2
- SEPTIN11 | c.818T>C p.L273P | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53582708; called by muse, mutect2
- SERPINB12 | c.989T>G p.L330R | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV54033557; called by muse, mutect2
- SERPINC1 | c.533T>G p.L178R | Missense Mutation (SNP) | VAF 11/228 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM034682, COSV62929637; called by muse, mutect2
- SETBP1 | c.2093C>A p.T698N | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV56324962; called by muse, mutect2, varscan2
- SGIP1 | c.869A>C p.D290A | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV52770890; called by muse, mutect2, varscan2
- SGPL1 | c.1698A>T p.K566N | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.036); catalogued as COSV64591349, COSV64591699; called by muse, mutect2
- SH2D2A | c.821A>C p.K274T | Missense Mutation (SNP) | VAF 27/366 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.07); catalogued as COSV63884940; called by muse, mutect2
- SIAH2 | c.781T>G p.F261V | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57262292; called by muse, mutect2, varscan2
- SIGLEC1 | c.368A>C p.N123T | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV52465457; called by muse, varscan2
- SIRPG | c.383A>G p.E128G | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV53807976; called by muse, mutect2
- SIX2 | c.503T>C p.V168A | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57391099; called by muse, mutect2
- SKIDA1 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.056); catalogued as rs755934011, COSV71610920; called by muse, varscan2
- SKIDA1 | c.1447T>G p.F483V | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.168); catalogued as COSV71610921; called by muse, varscan2
- SLC12A2 | c.796A>G p.T266A | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.489); catalogued as COSV52472213; called by muse, mutect2, varscan2
- SLC13A3 | c.427A>G p.S143G | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV51717087; called by muse, mutect2
- SLC19A1 | c.951C>T p.G317= | Splice Region (SNP) | VAF 3/12 reads (25%) | catalogued as COSV60753560; called by muse, mutect2
- SLC22A6 | c.677T>G p.I226S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV64560324; called by muse, mutect2, varscan2
- SLC25A45 | c.307T>G p.F103V | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.908); catalogued as COSV53684089; called by mutect2, varscan2
- SLC25A51 | c.770T>G p.I257S | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV99643380; called by muse, mutect2, varscan2
- SLC29A3 | c.148T>G p.F50V | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as COSV64385278; called by muse, mutect2, varscan2
- SLC34A2 | c.1156A>T p.I386F | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs1274419196, COSV65941814; called by muse, mutect2
- SLC39A11 | c.1013A>G p.D338G (on ENST00000542342 / NM_001159770.2; = p.D331G on NM_139177.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55290704; called by muse, mutect2, varscan2
- SLC39A14 | c.878A>G p.E293G | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.186); catalogued as COSV51484743; called by muse, mutect2
- SLC4A2 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV59657603; called by muse, mutect2, varscan2
- SLC4A3 | c.3446A>C p.K1149T | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV56094542; called by muse, mutect2
- SLC5A1 | c.782A>C p.D261A | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56685340, COSV56685989; called by muse, mutect2, varscan2
- SLCO3A1 | c.1136A>G p.Q379R | Missense Mutation (SNP) | VAF 75/271 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV59230181; called by muse, mutect2, varscan2
- SLITRK2 | c.368A>G p.E123G | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59426007; called by muse, mutect2, varscan2
- SMCHD1 | c.2444A>C p.K815T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV55259216; called by muse, mutect2, varscan2
- SNRPD2 | c.254A>G p.K85R | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV50004000; called by muse, mutect2, varscan2
- SNX31 | c.571A>G p.S191G | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV61263464; called by muse, varscan2
- SPATA19 | c.30T>G p.I10M | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV54483615; called by muse, mutect2
- SPEN | c.1000A>C p.S334R | Missense Mutation (SNP) | VAF 13/222 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65363139; called by muse, mutect2
- SPEN | c.2293A>T p.S765C | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65363143; called by muse, mutect2
- SPEN | c.3914A>T p.E1305V | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV65363146; called by muse, mutect2
- SPHKAP | c.3042A>C p.K1014N | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV60869905; called by muse, mutect2
- SPHKAP | c.1510G>A p.A504T | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV60882333; called by muse, mutect2
- SPRR2F | c.65A>C p.K22T | Missense Mutation (SNP) | VAF 35/343 reads (10%) | PolyPhen benign (0.349); catalogued as COSV64206230; called by muse, mutect2, varscan2
- SPTA1 | c.1901A>C p.K634T | Missense Mutation (SNP) | VAF 67/292 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as COSV63752423, COSV63761847; called by muse, mutect2, varscan2
- SPTBN5 | c.6974A>C p.K2325T | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV100311851; called by muse, mutect2
- SRBD1 | c.1396T>G p.C466G | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV55399753; called by muse, mutect2
- SRRM1 | c.302T>G p.F101C | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV60477996; called by muse, mutect2
- SRRM2 | c.6904A>C p.T2302P | Missense Mutation (SNP) | VAF 25/381 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV51940906; called by muse, mutect2
- ST6GAL2 | c.88T>G p.F30V | Missense Mutation (SNP) | VAF 12/62 reads (19%) | PolyPhen probably damaging (0.996); catalogued as rs138857139; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.539A>G p.D180G | Missense Mutation (SNP) | VAF 11/190 reads (6%) | PolyPhen possibly damaging (0.583); catalogued as COSV59566545; called by muse, mutect2
- ST8SIA1 | c.590A>G p.Q197R | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV53954898; called by muse, mutect2, varscan2
- STAB2 | c.4151A>G p.E1384G | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66340489; called by muse, mutect2, varscan2
- STUM | c.352T>G p.F118V | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.084); catalogued as COSV64684439; called by muse, mutect2
- STX16 | c.769T>G p.L257V (on ENST00000371141 / NM_001001433.3; = p.L236V on NM_003763.6) | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV56606324; called by muse, mutect2
- SULT1C3 | c.146T>G p.L49R | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100227535; called by muse, mutect2, varscan2
- SUOX | c.831A>C p.E277D | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV99907149; called by muse, mutect2, varscan2
- SWT1 | c.324T>G p.N108K | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as rs912004903, COSV62255828; called by muse, mutect2
- SYCP2 | c.2007A>C p.K669N | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.625); catalogued as COSV62769035; called by muse, mutect2
- SYNE1 | c.7322T>G p.V2441G (on ENST00000367255 / NM_182961.4; = p.V2448G on NM_033071.3) | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV55003940; called by muse, mutect2, varscan2
- SYNJ1 | c.4376A>C p.K1459T | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.053); catalogued as COSV59149856; called by muse, mutect2, varscan2
- SYNPO2 | c.1780G>A p.G594R | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61112113; called by muse, mutect2, varscan2
- SYT11 | c.393A>C p.E131D | Missense Mutation (SNP) | VAF 20/275 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.101); catalogued as COSV64174756; called by muse, mutect2
- SYT3 | c.962T>C p.L321P | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58897199; called by muse, mutect2
- SZT2 | c.583G>T p.D195Y | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); catalogued as COSV63034942; called by muse, mutect2, varscan2
- TACC2 | c.7527A>C p.K2509N (on ENST00000334433; = p.K587N on NM_006997.4) | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV53282530; called by muse, mutect2, varscan2
- TAF11 | c.567A>C p.E189D | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51956248; called by muse, mutect2
- TAF1L | c.1351A>C p.S451R | Missense Mutation (SNP) | VAF 49/225 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.082); catalogued as COSV54263138; called by muse, mutect2, varscan2
- TAF4 | c.1905A>T p.E635D | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53338236; called by muse, mutect2
- TAFA2 | c.269T>C p.V90A | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV69180455; called by muse, mutect2, varscan2
- TAMM41 | c.245A>G p.K82R | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as COSV56071989; called by muse, mutect2
- TAOK2 | c.359A>C p.K120T | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV54236683; called by muse, mutect2, varscan2
- TAS1R2 | c.1785A>G p.I595M | Missense Mutation (SNP) | VAF 103/198 reads (52%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV64745390; called by muse, mutect2, varscan2
- TAS2R42 | c.905T>G p.L302R | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100516899; called by muse, mutect2, varscan2
- TAT | c.623A>C p.K208T | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as COSV63532999; called by muse, mutect2, varscan2
- TBC1D1 | c.3470A>T p.E1157V | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.094); catalogued as COSV54720513; called by muse, mutect2
- TDP1 | c.1673A>C p.K558T | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as COSV59643731; called by muse, mutect2, varscan2
- TENM1 | c.3254A>C p.K1085T | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64431648; called by muse, mutect2
- TET1 | c.3533A>C p.K1178T | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV65385505; called by muse, mutect2, varscan2
- TF | c.1492T>A p.F498I | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs778098287, COSV53921036; called by muse, varscan2
- TF | c.1503A>C p.E501D | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as COSV53921046; called by muse, varscan2
- TG | c.4249T>G p.F1417V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55079667; called by muse, mutect2, varscan2
- THADA | c.5504A>C p.N1835T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746648119, COSV56698681; called by muse, mutect2, varscan2
- THBS1 | c.3022T>G p.F1008V | Missense Mutation (SNP) | VAF 34/452 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52952684; called by muse, mutect2
- THOC2 | c.1063A>G p.I355V | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as COSV55547645; called by muse, mutect2, varscan2
- THRB | c.1371A>C p.E457D | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as COSV54980635; called by muse, mutect2, varscan2
- TICRR | c.802A>G p.S268G | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV51542320; called by muse, mutect2
- TIGD4 | c.1416A>C p.K472N | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as COSV58549827; called by muse, mutect2, varscan2
- TLN1 | c.2569T>G p.L857V | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV59208273; called by muse, mutect2, varscan2
- TMCC1 | c.837A>C p.Q279H | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61440928; called by muse, mutect2, varscan2
- TMEM100 | c.84A>C p.E28D | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV70118077; called by muse, mutect2, varscan2
- TMEM131L | c.1061-2A>T p.X354_splice | Splice Site (SNP) | VAF 10/53 reads (19%) | catalogued as COSV53645517; called by muse, mutect2, varscan2
- TMEM145 | c.1054T>C p.F352L | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.424); catalogued as COSV56625678; called by muse, mutect2
- TMEM266 | c.96A>C p.E32D | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.041); catalogued as COSV66379741; called by muse, mutect2, varscan2
- TMEM43 | c.193G>C p.A65P | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.175); catalogued as COSV60146273; called by muse, mutect2, varscan2
- TMEM67 | c.2705T>A p.L902H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60040584; called by muse, mutect2, varscan2
- TNFRSF13B | c.439A>G p.S147G | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55428284; called by muse, mutect2, varscan2
- TNIK | c.3082A>G p.T1028A | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.186); catalogued as COSV52684537; called by muse, mutect2, varscan2
- TOX | c.738A>C p.K246N | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63846899; called by muse, mutect2, varscan2
- TP53 | c.484A>T p.I162F | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as CM1412385, COSV52675923, COSV52730390; called by muse, mutect2, varscan2
- TRIM42 | c.1340A>C p.K447T | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.063); catalogued as COSV53883751; called by muse, mutect2, varscan2
- TRIM61 | c.470T>G p.L157R | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV100255966, COSV100256152; called by muse, varscan2
- TRIM71 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.147); catalogued as COSV67471347; called by muse, mutect2, varscan2
- TRIOBP | c.950A>T p.E317V | Missense Mutation (SNP) | VAF 18/272 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV60378891; called by muse, mutect2
- TRMT5 | c.1075T>G p.F359V | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV54203735; called by muse, mutect2, varscan2
- TRPA1 | c.2686G>A p.D896N | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.438); catalogued as COSV51563807; called by muse, mutect2, varscan2
- TRPC1 | c.223T>G p.L75V | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV56426073; called by muse, mutect2, varscan2
- TRPM1 | c.1694A>C p.K565T | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as COSV99856283; called by muse, mutect2
- TSPAN10 | c.616G>T p.G206W (on ENST00000574882 / NM_001290212.1; = p.G168W on NM_031945.4) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100148599; called by muse, mutect2, varscan2
- TSPYL6 | c.889T>G p.F297V | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.69); catalogued as COSV57814798; called by muse, mutect2
- TSR3 | c.560A>C p.K187T | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as COSV50104118; called by muse, mutect2
- TTC8 | c.228A>C p.Q76H (on ENST00000338104 / NM_001288781.1; = p.Q86H on NM_144596.4) | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.601); catalogued as COSV100581640, COSV57628188; called by muse, mutect2, varscan2
- TTF1 | c.1181T>G p.L394R | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57504797; called by muse, mutect2, varscan2
- TTN | c.84101A>G p.K28034R (on ENST00000591111; = p.K20610R on NM_003319.4) | Missense Mutation (SNP) | VAF 41/175 reads (23%) | PolyPhen probably damaging (0.994); catalogued as COSV60114900; called by muse, mutect2, varscan2
- TTN | c.62513G>A p.G20838D (on ENST00000591111; = p.G13414D on NM_003319.4) | Missense Mutation (SNP) | VAF 54/104 reads (52%) | PolyPhen probably damaging (1); catalogued as COSV60114985; called by muse, mutect2, varscan2
- TTN | c.12148A>C p.K4050Q (on ENST00000591111; = p.K4004Q on NM_003319.4) | Missense Mutation (SNP) | VAF 14/84 reads (17%) | catalogued as COSV60115057; called by muse, mutect2, varscan2
- TTN | c.11955A>C p.K3985N (on ENST00000591111; = p.K3939N on NM_003319.4) | Missense Mutation (SNP) | VAF 4/64 reads (6%) | catalogued as COSV60115085; called by muse, mutect2
- TTN | c.3250T>C p.F1084L (on ENST00000591111; = p.F1038L on NM_003319.4) | Missense Mutation (SNP) | VAF 17/66 reads (26%) | PolyPhen probably damaging (0.987); catalogued as COSV60115105; called by muse, mutect2, varscan2
- TTYH2 | c.160G>A p.V54I | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs142378984; called by muse, mutect2, varscan2
- TUBA1A | c.491A>C p.K164T | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.412); catalogued as COSV55496513, COSV55497636; called by muse, mutect2, varscan2
- UBE2O | c.2858A>G p.K953R | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as rs1162731585, COSV60063913; called by muse, mutect2, varscan2
- UBE3B | c.497T>G p.L166R | Missense Mutation (SNP) | VAF 22/325 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99784234; called by muse, mutect2
- UBFD1 | c.770A>C p.K257T | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV54842131; called by muse, mutect2, varscan2
- UBTD2 | c.632A>T p.K211M | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV67143431; called by muse, mutect2, varscan2
- UBXN8 | c.653T>G p.F218C | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV55664950; called by muse, mutect2, varscan2
- ULK2 | c.1382A>G p.Q461R | Missense Mutation (SNP) | VAF 15/179 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.133); catalogued as COSV64446286; called by muse, mutect2
- UNC13B | c.823A>T p.S275C | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV65935398; called by muse, mutect2
- UNC13C | c.2725T>A p.S909T | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as COSV52882401; called by muse, mutect2, varscan2
- UNK | c.184T>C p.F62L | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV53142520; called by muse, mutect2
- USH2A | c.9602A>C p.K3201T | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as COSV100228343, COSV56381553; called by muse, mutect2, varscan2
- USP32 | c.2242A>G p.S748G | Missense Mutation (SNP) | VAF 21/225 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as COSV56270230; called by muse, mutect2
- UTP14A | c.1271T>G p.F424C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV64087087; called by muse, mutect2, varscan2
- VARS1 | c.3079T>C p.L1027= | Splice Region (SNP) | VAF 17/69 reads (25%) | catalogued as COSV63304725; called by muse, mutect2, varscan2
- VIRMA | c.5333T>C p.L1778P | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.571); catalogued as COSV52586087; called by muse, mutect2
- VNN1 | c.454T>G p.C152G | Missense Mutation (SNP) | VAF 13/197 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63390043; called by muse, mutect2
- VPS13D | c.3044A>C p.D1015A | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1285418672, COSV50645171; called by muse, mutect2, varscan2
- VPS54 | c.2582T>A p.L861H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55441443; called by muse, mutect2, varscan2
- VWF | c.4280T>G p.L1427R | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.494); catalogued as COSV54623058; called by muse, mutect2, varscan2
- WDCP | c.140A>G p.K47R | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as rs201455909; called by muse, mutect2, varscan2
- WDR41 | c.1130A>C p.K377T | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56999053; called by muse, mutect2
- WDR49 | c.1244T>G p.F415C (on ENST00000308378 / NM_001366158.1; = p.F756C on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57709621; called by muse, mutect2, varscan2
- WWC2 | c.671A>C p.E224A | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100968430; called by muse, mutect2
- XK | c.563A>C p.N188T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as COSV66120267, COSV66120981; called by muse, mutect2, varscan2
- XYLT1 | c.1803A>C p.E601D | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV54486321; called by muse, mutect2
- YTHDF2 | c.295T>G p.F99V | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV65723345; called by muse, mutect2, varscan2
- ZBTB40 | c.164A>C p.N55T | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as COSV65145547; called by muse, mutect2
- ZC3H7B | c.1420A>T p.T474S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.808); catalogued as COSV60962372; called by muse, mutect2, varscan2
- ZDBF2 | c.5825T>G p.I1942S | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV65626833; called by muse, mutect2
- ZDHHC13 | c.104T>C p.L35P | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV67981164; called by muse, mutect2, varscan2
- ZDHHC5 | c.1952_1954del p.E651del | In Frame Del (DEL) | VAF 36/90 reads (40%) | catalogued as rs749408941; called by pindel, varscan2
- ZDHHC8 | c.1067A>G p.K356R | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.81); catalogued as COSV57710855; called by muse, mutect2
- ZFAT | c.211A>C p.K71Q | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64739817; called by muse, mutect2, varscan2
- ZFYVE26 | c.2848A>C p.S950R | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV61329486; called by muse, mutect2, varscan2
- ZHX2 | c.590A>G p.K197R | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as rs757779343, COSV58713857; called by muse, mutect2, varscan2
- ZIM3 | c.213A>C p.E71D | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.05); catalogued as COSV54143528; called by muse, mutect2, varscan2
- ZNF235 | c.810A>C p.E270D | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV52156896; called by muse, mutect2
- ZNF334 | c.1418A>C p.K473T | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV61618917; called by muse, mutect2
- ZNF33B | c.630G>C p.E210D | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV63942680; called by muse, mutect2
- ZNF354C | c.452A>T p.E151V | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV59608556; called by muse, mutect2, varscan2
- ZNF408 | c.535A>T p.S179C | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as COSV61238422; called by muse, mutect2
- ZNF45 | c.1528A>G p.S510G | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs927583044, COSV54193389; called by muse, mutect2, varscan2
- ZNF461 | c.1211A>G p.Q404R | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.417); catalogued as COSV64453962; called by muse, mutect2, varscan2
- ZNF491 | c.592T>G p.F198V | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.062); catalogued as COSV60057705; called by muse, mutect2, varscan2
- ZNF491 | c.1225A>C p.K409Q | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV60057720; called by muse, mutect2, varscan2
- ZNF496 | c.1243T>G p.F415V | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); catalogued as COSV54174073; called by muse, mutect2, varscan2
- ZNF677 | c.281T>G p.F94C | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.903); catalogued as COSV61720472; called by muse, mutect2, varscan2
- ZNF781 | c.70C>G p.Q24E | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.298); catalogued as rs895889042, COSV62201685; called by muse, mutect2
- ZP4 | c.850A>C p.S284R | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.071); catalogued as COSV63912282; called by muse, mutect2, varscan2
- CCL3 | c.176A>C p.K59T | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- CNOT6L | c.1502T>C p.L501P (on ENST00000504123 / NM_001286790.2; = p.L496P on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); called by muse, mutect2
- COLEC10 | c.126_129del p.H42Qfs*100 | Frame Shift Del (DEL) | VAF 12/53 reads (23%) | called by mutect2, pindel, varscan2
- EPG5 | c.410A>C p.N137T | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); called by muse, mutect2
- GOLGA6L9 | c.107A>C p.K36T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.959); called by muse, varscan2
- IGLV5-37 | c.317A>C p.Q106P | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- IRF2BP2 | c.1658A>G p.E553G | Missense Mutation (SNP) | VAF 12/358 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MRC1 | c.3619A>C p.S1207R | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); called by muse, mutect2
- NAV2 | c.6558del p.I2187Sfs*46 (on ENST00000396087 / NM_001244963.2; = p.I2128Sfs*46 on NM_145117.5) | Frame Shift Del (DEL) | VAF 23/82 reads (28%) | called by mutect2, pindel, varscan2
- PIGR | c.1560dup p.D521* | Frame Shift Ins (INS) | VAF 38/95 reads (40%) | called by mutect2, pindel, varscan2
- RUBCN | c.1983C>A p.L661= | Splice Region (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2
- SGO1 | c.1290dup p.P431Tfs*2 (on ENST00000263753 / NM_001012410.5; = p.P162Tfs*2 on NM_138484.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 9/52 reads (17%) | called by mutect2, pindel, varscan2
- SRCIN1 | c.2750T>G p.L917R (on ENST00000621492; = p.L883R on NM_025248.3) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- TRGC2 | c.255A>C p.E85D | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- TSPYL6 | c.175del p.V59Sfs*32 | Frame Shift Del (DEL) | VAF 25/125 reads (20%) | called by mutect2, pindel, varscan2
- ACSM3 | c.927T>G p.T309= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as COSV55501934; called by muse, mutect2, varscan2
- ADAM7 | c.1560A>T p.I520= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV51541155; called by muse, mutect2, varscan2
- ADGRE1 | c.1716T>C p.A572= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV51676593; called by muse, mutect2, varscan2
- AGBL5 | c.990A>G p.K330= | Silent (SNP) | VAF 5/93 reads (5%) | catalogued as COSV59936702; called by muse, mutect2
- ANKFN1 | c.1455T>A p.S485= | Silent (SNP) | VAF 35/126 reads (28%) | catalogued as COSV59449479; called by muse, mutect2, varscan2
- ARNTL | c.420T>G p.T140= | Silent (SNP) | VAF 7/111 reads (6%) | catalogued as COSV62987045; called by muse, mutect2
- ATP13A2 | c.2271G>A p.A757= | Silent (SNP) | VAF 73/103 reads (71%) | catalogued as rs777302964, COSV58699605; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATP2A1 | c.1164T>G p.T388= | Silent (SNP) | VAF 13/21 reads (62%) | catalogued as COSV63921367; called by muse, mutect2, varscan2
- BRAF | c.1080A>G p.R360= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as COSV56209848; called by muse, mutect2, varscan2
- CCDC159 | c.84C>T p.S28= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV61514794; called by muse, mutect2, varscan2
- CD300C | c.447A>C p.S149= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV58169889, COSV58170623; called by mutect2, varscan2
- CDC5L | c.1464T>C p.N488= | Silent (SNP) | VAF 35/59 reads (59%) | catalogued as COSV65176251; called by muse, mutect2, varscan2
- CDNF | c.300T>C p.T100= | Silent (SNP) | VAF 54/184 reads (29%) | catalogued as COSV65805889; called by muse, mutect2, varscan2
- CHD6 | c.1908G>A p.E636= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as rs760090517, COSV58558088; called by muse, mutect2, varscan2
- CHRDL1 | c.708A>T p.S236= (on ENST00000372045; = p.S242= on NM_145234.4) | Silent (SNP) | VAF 45/125 reads (36%) | catalogued as COSV54325853; called by muse, mutect2, varscan2
- CLCN4 | c.1269T>G p.T423= | Silent (SNP) | VAF 30/236 reads (13%) | catalogued as COSV66466900; called by muse, mutect2, varscan2
- CNTN3 | c.1428T>G p.T476= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV55165301, COSV55184374; called by muse, mutect2, varscan2
- COL18A1 | c.3234G>T p.G1078= (on ENST00000359759 / NM_130444.3; = p.G843= on NM_030582.4) | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV60589570; called by muse, mutect2
- COL4A1 | c.1434T>A p.P478= | Silent (SNP) | VAF 5/77 reads (6%) | catalogued as COSV65427042; called by muse, mutect2
- COL4A4 | c.4422G>A p.T1474= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs750682352, COSV61633007; called by muse, mutect2, varscan2
- COL6A3 | c.1851G>A p.L617= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV55111619; called by muse, mutect2
- CPNE9 | c.1296T>C p.T432= | Silent (SNP) | VAF 16/114 reads (14%) | catalogued as rs750074695, COSV56068737; called by muse, mutect2, varscan2
- CRACDL | c.2490T>C p.T830= | Silent (SNP) | VAF 22/125 reads (18%) | catalogued as COSV67408506; called by muse, mutect2, varscan2
- CRMP1 | c.495A>G p.Q165= | Silent (SNP) | VAF 19/257 reads (7%) | catalogued as COSV61480817; called by muse, mutect2
- CSMD2 | c.7341T>G p.R2447= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV53920175; called by muse, mutect2, varscan2
- CTSV | c.57A>G p.P19= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV52344969; called by muse, mutect2, varscan2
- CYFIP2 | c.1974A>T p.R658= (on ENST00000616178 / NM_001291722.2; = p.R633= on NM_014376.4) | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV59040902; called by muse, mutect2, varscan2
- DBF4B | c.511C>T p.L171= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV59261124; called by muse, mutect2, varscan2
- DENND2B | c.336C>T p.D112= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs764113378, COSV58204440; called by muse, mutect2, varscan2
- DHX16 | c.1774T>C p.L592= | Silent (SNP) | VAF 3/48 reads (6%) | catalogued as rs746783354, COSV100905222; called by muse, mutect2
- DHX58 | c.1284A>G p.Q428= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs960604599, COSV52426277; called by muse, mutect2, varscan2
- DIP2B | c.4719T>G p.A1573= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV56585433; called by muse, mutect2, varscan2
- DMRT2 | c.993T>C p.T331= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV52402163; called by muse, mutect2, varscan2
- DOCK2 | c.1707T>G p.P569= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV56962992; called by muse, mutect2, varscan2
- DTX3L | c.1614T>C p.A538= | Silent (SNP) | VAF 11/111 reads (10%) | catalogued as COSV56144463; called by muse, mutect2, varscan2
- DVL2 | c.324A>G p.A108= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as rs1567575128, COSV50036576; called by muse, mutect2, varscan2
- ECI1 | c.870G>T p.L290= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV57039420; called by muse, mutect2, varscan2
- ELOA | c.2199T>C p.H733= | Silent (SNP) | VAF 56/548 reads (10%) | catalogued as rs140332205; called by muse, mutect2
- F2 | c.6G>A p.A2= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs748368751, COSV61316049; called by muse, mutect2, varscan2
- F5 | c.1446T>G p.T482= | Silent (SNP) | VAF 9/244 reads (4%) | catalogued as COSV63124952; called by muse, mutect2
- FAM107A | c.114G>A p.V38= | Silent (SNP) | VAF 7/102 reads (7%) | catalogued as COSV62980724; called by muse, mutect2
- FAM126A | c.618T>C p.I206= | Silent (SNP) | VAF 7/77 reads (9%) | catalogued as COSV69017183; called by muse, mutect2
- FAM168A | c.219T>A p.S73= (on ENST00000064778 / NM_001286050.2; = p.S64= on NM_015159.3) | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV50358221; called by muse, mutect2, varscan2
- FAM186B | c.1947T>C p.S649= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV57721841; called by muse, mutect2, varscan2
- FAT3 | c.4965A>G p.A1655= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as rs1435686226, COSV53121520; called by muse, mutect2, varscan2
- FBXL14 | c.1231A>C p.R411= | Silent (SNP) | VAF 5/66 reads (8%) | catalogued as COSV59336576; called by muse, mutect2
- FGD5 | c.2082A>G p.E694= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as COSV53244657; called by muse, mutect2
- GRIK4 | c.132C>T p.S44= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as rs184718356, COSV70803017; ClinVar: likely benign; called by muse, mutect2, varscan2
- GYPE | c.105C>A p.V35= | Silent (SNP) | VAF 25/155 reads (16%) | catalogued as COSV62262415; called by muse, mutect2, varscan2
- HAUS6 | c.397A>C p.R133= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV63252958; called by muse, mutect2, varscan2
- HERC1 | c.6919C>T p.L2307= | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as COSV71248184; called by muse, mutect2, varscan2
- HSPA1L | c.258A>G p.Q86= | Silent (SNP) | VAF 13/226 reads (6%) | catalogued as COSV65149129; called by muse, mutect2
- HSPA5 | c.114C>A p.T38= | Silent (SNP) | VAF 46/126 reads (37%) | catalogued as COSV61029333; called by muse, mutect2, varscan2
- IFNA5 | c.541T>C p.L181= | Silent (SNP) | VAF 48/253 reads (19%) | catalogued as COSV52386966, COSV99423612; called by muse, mutect2, varscan2
- ING1 | c.201T>G p.G67= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV58169720; called by muse, mutect2
- INSRR | c.3234A>G p.A1078= | Silent (SNP) | VAF 12/242 reads (5%) | catalogued as COSV63874346; called by muse, mutect2
- IQGAP1 | c.1446A>G p.S482= | Silent (SNP) | VAF 17/177 reads (10%) | catalogued as rs1400993099, COSV51586694; called by muse, mutect2
- ITSN1 | c.1725A>G p.K575= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as COSV66083759; called by muse, mutect2, varscan2
- JAK1 | c.1833T>G p.T611= | Silent (SNP) | VAF 11/184 reads (6%) | catalogued as rs866613472, COSV61092148; called by muse, mutect2
- KCNA3 | c.1044C>T p.A348= | Silent (SNP) | VAF 67/112 reads (60%) | catalogued as rs756328280, COSV63901787; called by muse, mutect2, varscan2
- KCNA7 | c.1260T>A p.P420= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as COSV55503615; called by muse, mutect2, varscan2
- KIAA1549 | c.1470C>T p.I490= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs1280823844, COSV54316709; called by muse, mutect2, varscan2
- LIN28B | c.570T>C p.T190= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV61495489; called by muse, mutect2, varscan2
- LOXL3 | c.1119A>G p.E373= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as rs1333243951, COSV51208587, COSV99239610; called by muse, mutect2, varscan2
- LPA | c.4119T>G p.P1373= | Silent (SNP) | VAF 23/150 reads (15%) | catalogued as COSV60303245; called by muse, mutect2
- LPAR3 | c.345T>G p.A115= | Silent (SNP) | VAF 34/432 reads (8%) | catalogued as COSV65453828; called by muse, mutect2
- LRRCC1 | c.1533A>G p.K511= | Silent (SNP) | VAF 15/113 reads (13%) | catalogued as COSV64483735, COSV64486028; called by muse, mutect2, varscan2
- LTK | c.2433T>A p.S811= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV99541073; called by muse, mutect2, varscan2
- LY75 | c.4632T>C p.G1544= | Silent (SNP) | VAF 21/189 reads (11%) | catalogued as COSV55107238; called by muse, mutect2, varscan2
- MAPKAPK3 | c.501C>T p.V167= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs192866693; called by muse, mutect2, varscan2
- MFAP3L | c.1077T>G p.P359= | Silent (SNP) | VAF 28/132 reads (21%) | catalogued as rs142121641; called by muse, mutect2, varscan2
- MIA3 | c.4704T>G p.T1568= | Silent (SNP) | VAF 57/119 reads (48%) | catalogued as COSV60513902; called by muse, mutect2, varscan2
- MUC16 | c.17412A>G p.S5804= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV67472056; called by muse, mutect2, varscan2
- MUC16 | c.12573A>C p.S4191= | Silent (SNP) | VAF 5/56 reads (9%) | catalogued as COSV67472068; called by muse, mutect2
- MUC17 | c.9591T>G p.T3197= | Silent (SNP) | VAF 32/368 reads (9%) | catalogued as COSV60291271; called by muse, mutect2
- MXRA5 | c.2982A>G p.K994= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as COSV54238231; called by muse, mutect2, varscan2
- MYH2 | c.3927A>G p.R1309= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV55440021; called by muse, mutect2, varscan2
- MYLK | c.4503A>G p.K1501= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV60612262; called by muse, mutect2, varscan2
- NAALADL1 | c.798T>C p.S266= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV60524360; called by muse, mutect2, varscan2
- NLRP7 | c.543C>T p.G181= | Silent (SNP) | VAF 17/160 reads (11%) | catalogued as rs752629343, COSV60175839; called by muse, mutect2, varscan2
- OR14I1 | c.561C>T p.S187= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as COSV61199810; called by muse, mutect2, varscan2
- OR4C6 | c.90T>C p.L30= | Silent (SNP) | VAF 17/151 reads (11%) | catalogued as COSV58604428; called by muse, mutect2, varscan2
- OR4K17 | c.844T>C p.L282= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV59648346; called by muse, mutect2, varscan2
- PCDH15 | c.2569A>C p.R857= | Silent (SNP) | VAF 31/153 reads (20%) | catalogued as COSV57265882; called by muse, mutect2, varscan2
- PCDH18 | c.570T>A p.T190= | Silent (SNP) | VAF 38/63 reads (60%) | catalogued as COSV61269112; called by muse, mutect2, varscan2
- PCDHA10 | c.1386C>T p.F462= | Silent (SNP) | VAF 35/131 reads (27%) | catalogued as rs987628518, COSV56510213; called by muse, mutect2, varscan2
- PEG3 | c.4236A>G p.E1412= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as COSV55625532, COSV55636235; called by muse, mutect2, varscan2
- PI4KA | c.2922C>T p.N974= | Silent (SNP) | VAF 15/254 reads (6%) | catalogued as rs1218482922, COSV55413280; called by muse, mutect2
- PLA2R1 | c.1374C>T p.V458= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV51780271; called by muse, mutect2, varscan2
- POTEE | c.411A>C p.G137= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as COSV58233180; called by muse, mutect2, varscan2
- PRLR | c.928T>C p.L310= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as COSV51496591; called by muse, mutect2, varscan2
- PTPN12 | c.456A>G p.E152= | Silent (SNP) | VAF 7/85 reads (8%) | catalogued as COSV50360730; called by muse, mutect2
- PTPRZ1 | c.1557T>A p.T519= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV66438254; called by muse, mutect2, varscan2
- RALGAPA2 | c.1104G>A p.S368= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as rs751734959, COSV52493782, COSV99173744; called by muse, mutect2, varscan2
- RNF150 | c.762A>G p.K254= | Silent (SNP) | VAF 6/121 reads (5%) | catalogued as COSV60791894; called by muse, mutect2
- RNF39 | c.1020C>T p.R340= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV54993561; called by muse, mutect2
- RSAD2 | c.465G>A p.V155= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs747348742, COSV65908418; called by muse, mutect2, varscan2
- SDHB | c.271A>C p.R91= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV100973473; called by muse, mutect2
- SEMA5B | c.3378T>C p.T1126= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV52100171, COSV52109590; called by muse, mutect2, varscan2
- SETBP1 | c.4062A>C p.S1354= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV56324973; called by muse, mutect2, varscan2
- SFTPA2 | c.570T>C p.T190= | Silent (SNP) | VAF 25/247 reads (10%) | catalogued as COSV64882583; called by muse, mutect2, varscan2
- SHANK2 | c.4407A>G p.S1469= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV53601819; called by muse, mutect2
- SIGLEC6 | c.750C>T p.S250= | Silent (SNP) | VAF 23/30 reads (77%) | catalogued as rs745563782, COSV58432366; called by muse, mutect2, varscan2
- SLC23A3 | c.306T>C p.T102= | Silent (SNP) | VAF 18/240 reads (8%) | catalogued as rs1029362350, COSV55407880; called by muse, mutect2
- SLC44A5 | c.2133A>G p.Q711= | Silent (SNP) | VAF 46/146 reads (32%) | catalogued as COSV63766881; called by muse, mutect2, varscan2
- SLC9B1 | c.711A>G p.Q237= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as COSV56470959; called by muse, mutect2, varscan2
- SPACA7 | c.66T>G p.T22= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs758699501, COSV52100541; called by muse, mutect2, varscan2
47 further variants in this file (0 protein-altering or splice-affecting, 28 silent, 19 other) are not listed here.
